Somatic mutation profile of tumor specimen 0DJGE4 from CCDI case PBBWNC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.9 years (5,805 days).
Specimen 0DJGE4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef0bac20-2b32-49e4-979f-970272dee9a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJG6Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23fdd906-cb5d-416d-8af0-2df6f70e32e8

The open-access MAF lists 57 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, 5'UTR 2, 3'UTR 2, Nonsense Mutation 1, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 143/830 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 228/1452 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 359/745 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, varscan2
- ANKK1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 154/725 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs771060056, COSV58272467; called by muse, varscan2
- AP3B2 | c.2794+4C>T | Splice Region (SNP) | VAF 144/670 reads (21%) | catalogued as rs751527164, COSV55606993; called by muse, varscan2
- ASCC3 | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 291/1291 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs772379539, COSV61230780; called by muse, varscan2
- CECR2 | c.1879C>G p.R627G (on ENST00000342247 / NM_001290047.2; = p.R444G on NM_001290046.1) | Missense Mutation (SNP) | VAF 162/762 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1304791646, COSV99378009; called by muse, varscan2
- CNGA4 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 176/804 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66005589; called by muse, varscan2
- COL18A1 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 94/476 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as rs780737161; called by muse, varscan2
- DIP2A | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 87/502 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778399012, COSV59473519; called by muse, varscan2
- EZH2 | c.1710G>T p.Q570H (on ENST00000460911 / NM_001203247.2; = p.Q575H on NM_004456.5) | Missense Mutation (SNP) | VAF 368/1125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57452798, COSV57454994; called by muse, varscan2
- F5 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 210/878 reads (24%) | catalogued as rs770011773, HM971410, COSV63120371; called by muse, varscan2
- FIZ1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 96/327 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV55609470; called by muse, varscan2
- FNDC1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 124/441 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs1440002539; called by muse, varscan2
- GREB1L | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 180/728 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as rs1475163053; called by muse, varscan2
- KLHL3 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 148/638 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553674; called by muse, varscan2
- KSR2 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 228/912 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs759297631; called by muse, varscan2
- MAP4K1 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 116/546 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV101204219; called by muse, varscan2
- NKX2-5 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs759518211; called by muse, varscan2
- RBL1 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 156/716 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775096450, COSV60331234; called by muse, varscan2
- SLC8A2 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV52639598; called by muse, varscan2
- TCP10L2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 164/1248 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.034); catalogued as rs577537940; called by muse, varscan2
- UNC13A | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 180/730 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53200305; called by muse, varscan2
- ADGRG1 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ATRX | c.3244_3245del p.S1082* | Frame Shift Del (DEL) | VAF 336/1308 reads (26%) | called by pindel, varscan2
- GDF2 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 126/732 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- GRIN2B | c.4334A>C p.D1445A | Missense Mutation (SNP) | VAF 170/582 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, varscan2
- LCE3B | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 202/435 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.958); called by muse, varscan2
- NEK9 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 58/522 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, varscan2
- NUP62 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 122/501 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, varscan2
- RIMS1 | c.4946C>G p.S1649C | Missense Mutation (SNP) | VAF 220/999 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- RYR3 | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 252/1167 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.116); called by muse, varscan2
- SPHKAP | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 206/876 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, varscan2
- SRC | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 206/776 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- TMEM160 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, varscan2
- TRMT10A | c.133A>T p.M45L | Missense Mutation (SNP) | VAF 318/1468 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- USP17L7 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 110/1478 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, varscan2
- ZACN | c.170G>C p.S57T | Missense Mutation (SNP) | VAF 166/714 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, varscan2
- ABCA2 | c.3546G>A p.A1182= (on ENST00000614293; = p.A1152= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 112/752 reads (15%) | catalogued as rs370141589; called by muse, varscan2
- ATP8A2 | c.1527G>A p.T509= | Silent (SNP) | VAF 178/1030 reads (17%) | catalogued as COSV54936726; called by muse, varscan2
- CALML5 | c.183C>T p.D61= | Silent (SNP) | VAF 138/628 reads (22%) | catalogued as rs549120790, COSV66702427; called by muse, varscan2
- FER1L5 | c.1356C>T p.P452= (on ENST00000623019; = p.P457= on NM_001293083.2) | Silent (SNP) | VAF 220/874 reads (25%) | catalogued as rs373878629; called by muse, varscan2
- GNAS | c.1746C>T p.D582= | Silent (SNP) | VAF 137/436 reads (31%) | catalogued as COSV58341157; called by muse, varscan2
- KCNMA1 | c.1239C>T p.C413= | Silent (SNP) | VAF 136/631 reads (22%) | catalogued as rs139515379; ClinVar: likely benign; called by muse, varscan2
- MYH8 | c.4002C>T p.H1334= | Silent (SNP) | VAF 216/1306 reads (17%) | catalogued as rs140081412, COSV67962792; called by muse, varscan2
- PA2G4 | c.1014C>T p.F338= | Silent (SNP) | VAF 216/873 reads (25%) | catalogued as rs147419782; called by muse, varscan2
- PCDHB6 | c.2088G>T p.S696= | Silent (SNP) | VAF 54/242 reads (22%) | catalogued as rs151095667, COSV50727495; called by muse, varscan2
- PCDHGA7 | c.2214G>A p.S738= | Silent (SNP) | VAF 152/640 reads (24%) | catalogued as rs541716228, COSV53997825, COSV99535093; called by muse, varscan2
- SEMG2 | c.867G>A p.P289= | Silent (SNP) | VAF 298/1366 reads (22%) | catalogued as rs369755538; called by muse, varscan2
- SZT2 | c.4956A>G p.P1652= (on ENST00000634258 / NM_001365999.1; = p.P1595= on NM_015284.4) | Silent (SNP) | VAF 136/616 reads (22%) | catalogued as COSV65169134; called by muse, varscan2
- TMEM201 | c.408C>T p.A136= | Silent (SNP) | VAF 182/741 reads (25%) | catalogued as rs1210141364, COSV61052256, COSV61052574; called by muse, varscan2
- ZNF154 | c.541A>C p.R181= | Silent (SNP) | VAF 94/619 reads (15%) | called by muse, varscan2
- DPP10 | c.-8C>T | 5'UTR (SNP) | VAF 157/716 reads (22%) | called by muse, varscan2
- KCNJ8 | c.*20C>G | 3'UTR (SNP) | VAF 134/481 reads (28%) | catalogued as rs1039007053; called by muse, varscan2
- LGSN | c.-3G>C | 5'UTR (SNP) | VAF 306/1358 reads (23%) | called by muse, varscan2
- STX1A | c.209-44C>T | Intron (SNP) | VAF 79/350 reads (23%) | catalogued as rs782203664; called by muse, varscan2
- TRIL | c.*45C>T | 3'UTR (SNP) | VAF 70/252 reads (28%) | called by muse, varscan2
